Somatic mutation profile of tumor specimen TCGA-EE-A2MK-06A (aliquot TCGA-EE-A2MK-06A-11D-A196-08) from TCGA case TCGA-EE-A2MK, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 21.4 years (7,834 days).
Specimen TCGA-EE-A2MK-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c276b79-5580-42f6-bea1-e6495b24dbe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MK-10A (Blood Derived Normal), aliquot TCGA-EE-A2MK-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec26f783-257d-4ee4-8526-199dcd986bdd

The open-access MAF lists 346 somatic variants for this specimen: 226 protein-altering or splice-affecting, 115 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 207, Silent 115, Nonsense Mutation 11, Splice Region 4, Intron 3, Frame Shift Del 2, Splice Site 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA8 | c.3638G>A p.G1213E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV52207835; called by muse, mutect2, varscan2
- ABCC3 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53326098; called by muse, mutect2, varscan2
- ACTA2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (1); catalogued as COSV56517515; called by muse, mutect2, varscan2
- ACTRT1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 30/66 reads (45%) | catalogued as COSV64419785; called by muse, mutect2
- ADAMTS16 | c.1708C>G p.R570G | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56999696; called by muse, mutect2, varscan2
- ADAMTS3 | c.2416A>T p.I806F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV54397557; called by muse, varscan2
- ADCYAP1R1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58445354; called by muse, mutect2, varscan2
- ADGRB3 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs1298342083, COSV65409505; called by muse, mutect2, varscan2
- ADGRL1 | c.1540C>T p.Q514* (on ENST00000340736 / NM_001008701.3; = p.Q509* on NM_014921.5) | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV61565864; called by muse, mutect2, varscan2
- ADGRV1 | c.5725C>T p.P1909S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as rs781507717, COSV67991286; called by mutect2, varscan2
- ADH1B | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs768162102, COSV59295799; called by mutect2, varscan2
- AL121899.2 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV67351739; called by muse, mutect2, varscan2
- ANK2 | c.10384G>A p.E3462K | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.254); catalogued as COSV52177084; called by muse, mutect2, varscan2
- ARMCX2 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.121); catalogued as COSV57530784; called by muse, mutect2, varscan2
- ASB15 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.467); catalogued as rs775306192, COSV51928063; called by mutect2, varscan2
- AZGP1 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV52798581; called by muse, mutect2
- BCL9L | c.4262T>C p.M1421T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs754973656, COSV52687401; called by muse, mutect2, varscan2
- BRCA2 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs1566224551, COSV66458882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.4862C>T p.S1621F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100956630, COSV64751616; called by muse, mutect2, varscan2
- BRWD3 | c.2593G>A p.G865R | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64751624; called by muse, mutect2, varscan2
- BSN | c.3211G>A p.A1071T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV99609125; called by muse, mutect2
- C16orf78 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV54555026; called by muse, mutect2, varscan2
- C2CD2L | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.604); catalogued as COSV60884474; called by muse, mutect2, varscan2
- CAMK1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV56539747, COSV99844935; called by muse, mutect2, varscan2
- CCDC185 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as rs1408264347, COSV100838815; called by muse, mutect2, varscan2
- CCNE2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 258/490 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV57376966; called by muse, mutect2, varscan2
- CDCP1 | c.2165T>G p.F722C | Missense Mutation (SNP) | VAF 166/296 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56107017; called by muse, mutect2, varscan2
- CFAP54 | c.5249C>T p.S1750F | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs781170994, COSV100733493, COSV61573763; called by muse, mutect2, varscan2
- CHD3 | c.4649C>T p.P1550L | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as rs764171230, COSV57878109; called by muse, mutect2, varscan2
- CPS1 | c.4468C>T p.H1490Y | Missense Mutation (SNP) | VAF 70/95 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs1393116118, COSV51818404; called by muse, mutect2, varscan2
- CRHR1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV53282664; called by muse, mutect2, varscan2
- CSE1L | c.1438C>T p.L480F | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53703675; called by muse, mutect2, varscan2
- CSMD2 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 67/87 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53935040, COSV53938795; called by muse, mutect2, varscan2
- CYP2C8 | c.1370A>T p.N457I | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV64878131; called by muse, varscan2
- DCC | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV59120862; called by muse, mutect2, varscan2
- DGKI | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55965242; called by muse, mutect2, varscan2
- DMRT2 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 75/100 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV52402742; called by muse, mutect2, varscan2
- DNAH8 | c.5468C>T p.P1823L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59467086; called by muse, mutect2
- DNAH9 | c.10247C>T p.P3416L | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV52364578; called by muse, mutect2, varscan2
- DNAH9 | c.12344G>A p.G4115E | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52364590; called by muse, mutect2, varscan2
- DNAH9 | c.13367G>C p.R4456P | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52364602, COSV99305914; called by muse, mutect2
- DPPA2 | c.855G>A p.R285= | Splice Region (SNP) | VAF 36/127 reads (28%) | catalogued as COSV72118223; called by muse, mutect2, varscan2
- DRP2 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV65811173; called by muse, mutect2, varscan2
- DSCAM | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as COSV68648835; called by mutect2, varscan2
- ELFN2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1176640464, COSV68744053; called by muse, mutect2, varscan2
- EPB42 | c.1831C>T p.Q611* (on ENST00000441366 / NM_001114134.2; = p.Q641* on NM_000119.3) | Nonsense Mutation (SNP) | VAF 62/79 reads (78%) | catalogued as COSV55749048; called by muse, mutect2, varscan2
- EPHA2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV100626213; called by muse, mutect2, varscan2
- ERICH5 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV59316615; called by muse, mutect2, varscan2
- EZHIP | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100539798; called by muse, mutect2, varscan2
- FAM107A | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as COSV100723929, COSV62980989; called by muse, mutect2, varscan2
- FAM81B | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs1442255186, COSV51985497; called by muse, mutect2, varscan2
- FAM9A | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV66813566; called by muse, mutect2, varscan2
- FAT4 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as COSV67894549; called by muse, mutect2, varscan2
- FGD2 | c.1029G>A p.L343= | Splice Region (SNP) | VAF 26/60 reads (43%) | catalogued as COSV51465116; called by muse, mutect2
- FHL3 | c.598T>C p.F200L | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV65952733; called by muse, mutect2, varscan2
- FLG | c.4577del p.G1526Efs*180 | Frame Shift Del (DEL) | VAF 238/395 reads (60%) | catalogued as COSV64235652; called by pindel, varscan2
- FLNC | c.5330C>T p.P1777L | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV57960860; called by muse, mutect2, varscan2
- FMNL3 | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.54); PolyPhen benign (0.323); catalogued as COSV53305422; called by muse, mutect2, varscan2
- FMO3 | c.899A>C p.K300T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63008028; called by muse, mutect2, varscan2
- FOXD4 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV100071088; called by muse, mutect2, varscan2
- FOXD4 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV100071090; called by muse, mutect2, varscan2
- FOXH1 | c.1081T>A p.S361T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.116); catalogued as COSV56762171; called by mutect2, varscan2
- FSCN1 | c.1059G>C p.K353N | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61018292; called by muse, mutect2, varscan2
- FUT5 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | catalogued as COSV53137691; called by muse, mutect2, varscan2
- GABRA3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 74/109 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64802699; called by muse, varscan2
- GAD1 | c.1128G>A p.W376* | Nonsense Mutation (SNP) | VAF 22/29 reads (76%) | catalogued as COSV64026946; called by muse, mutect2, varscan2
- GDA | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV52995946; called by muse, mutect2, varscan2
- GEMIN5 | c.2149C>T p.H717Y | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs1219742237, COSV53563077; called by muse, mutect2, varscan2
- GOLPH3 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224334840, COSV54061882; called by muse, mutect2, varscan2
- GON4L | c.3386C>T p.P1129L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV55199003; called by muse, mutect2, varscan2
- GORAB | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated (0.43); PolyPhen benign (0.054); catalogued as COSV63026548; called by muse, mutect2, varscan2
- GPRASP1 | c.3272T>C p.L1091P | Missense Mutation (SNP) | VAF 130/332 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV64356155; called by muse, mutect2, varscan2
- GRIA2 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52380949; called by muse, mutect2, varscan2
- GRID2 | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56237676; called by muse, mutect2, varscan2
- GRIK2 | c.1847T>C p.V616A | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV59755366; called by muse, mutect2, varscan2
- GRIN2A | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs587780349, COSV58020005, COSV58059516; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRM8 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58849907; called by muse, mutect2, varscan2
- H2AC1 | c.236T>A p.I79N | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51237864; called by muse, mutect2, varscan2
- HCK | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs761716878, COSV52944469; called by mutect2, varscan2
- HDX | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1442068679, COSV99947669; called by muse, mutect2, varscan2
- HYAL4 | c.1202A>G p.N401S | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1312644872, COSV56139595; called by muse, mutect2, varscan2
- INAVA | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 109/213 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as rs761732608, COSV66256390; called by muse, mutect2, varscan2
- JAM2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as rs550982612, COSV57259253; called by mutect2, varscan2
- JAM2 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs766898080, COSV57259270; called by mutect2, varscan2
- KATNIP | c.914T>C p.F305S | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV55187474; called by muse, mutect2, varscan2
- KCNJ1 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.206); catalogued as rs1289183942, COSV60662368; called by muse, mutect2, varscan2
- KCNJ15 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.744); catalogued as rs1256338037, COSV60811548; called by muse, mutect2, varscan2
- KCNK9 | c.294C>G p.H98Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57283139, COSV57285673; called by muse, mutect2
- KCNV1 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52086210; called by muse, mutect2, varscan2
- KDM5A | c.3602C>T p.S1201F | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs867384215, COSV66994850; called by muse, mutect2, varscan2
- KIAA0232 | c.2221G>T p.D741Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs1225501011, COSV56927536; called by mutect2, varscan2
- KIAA1217 | c.3049G>A p.G1017R | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as rs1369884995, COSV56820395; called by muse, mutect2, varscan2
- KLHDC10 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as COSV59053122; called by muse, mutect2, varscan2
- LDHC | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55005251; called by muse, mutect2, varscan2
- LILRB5 | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.067); catalogued as COSV60259775; called by muse, mutect2, varscan2
- LINGO4 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as COSV59094562; called by muse, mutect2, varscan2
- LMBRD2 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56948873; called by mutect2, varscan2
- LRP12 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV52632033; called by muse, mutect2, varscan2
- LRRTM4 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV69141139; called by muse, mutect2, varscan2
- MAP7D3 | c.1233G>C p.E411D | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); catalogued as COSV60171880; called by muse, mutect2, varscan2
- MCF2 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.478); catalogued as COSV100644916; called by muse, mutect2, varscan2
- METTL2B | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52310036; called by muse, mutect2
- MFSD9 | c.637+1G>A p.X213_splice | Splice Site (SNP) | VAF 28/35 reads (80%) | catalogued as rs367802311; called by muse, mutect2, varscan2
- MGAM | c.3166G>A p.D1056N | Missense Mutation (SNP) | VAF 84/116 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV72075201; called by muse, mutect2, varscan2
- MUC16 | c.38423G>A p.R12808K | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs752560952, COSV67480995; called by muse, mutect2, varscan2
- MUC16 | c.15355C>T p.P5119S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV67449282; called by muse, mutect2, varscan2
- MXRA5 | c.8268G>A p.M2756I | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs1411285154, COSV54243496; called by muse, mutect2, varscan2
- MXRA5 | c.5533A>G p.K1845E | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV54243513; called by muse, mutect2, varscan2
- MYCBPAP | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV60410016; called by muse, mutect2, varscan2
- MYH13 | c.3895G>A p.E1299K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52836665; called by muse, mutect2, varscan2
- MYH7B | c.3317A>T p.D1106V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53423119; called by mutect2, varscan2
- MYO15A | c.9571C>T p.R3191C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297765168, COSV99233632, COSV99234697; called by mutect2, varscan2
- MYO1C | c.712C>T p.H238Y (on ENST00000648651 / NM_001080779.2; = p.H203Y on NM_033375.5) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63000157; called by muse, mutect2, varscan2
- MYO5B | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV53225737; called by muse, mutect2, varscan2
- MYOM1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV55295065; called by muse, mutect2, varscan2
- NEK9 | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 20/32 reads (63%) | catalogued as rs1050841917, COSV53132512; called by mutect2, varscan2
- NELL1 | c.1099A>T p.M367L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54239502, COSV54298699; called by muse, mutect2, varscan2
- NELL2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.44); PolyPhen benign (0.13); catalogued as COSV100418415, COSV61581141; called by muse, mutect2, varscan2
- NES | c.4495G>A p.E1499K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV63962055; called by muse, mutect2, varscan2
- NID1 | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV51625281; called by muse, mutect2, varscan2
- NLRP11 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.316); catalogued as COSV64088304; called by muse, mutect2, varscan2
- NLRP12 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as COSV60751484; called by muse, mutect2, varscan2
- NMD3 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.018); catalogued as COSV63619061; called by muse, mutect2, varscan2
- NOS1 | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as rs776589468, COSV57617680; called by muse, mutect2, varscan2
- NOS3 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52493104; called by muse, mutect2
- NSDHL | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs782406401, COSV64744793; called by muse, mutect2, varscan2
- OR10X1 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.079); catalogued as COSV63767729; called by muse, mutect2, varscan2
- OR4K5 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60002427, COSV60004795; called by muse, mutect2, varscan2
- OR51S1 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs1189256442, COSV59059174; called by muse, mutect2, varscan2
- OR5AC2 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV62279883; called by muse, mutect2, varscan2
- OR5L2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65724647; called by muse, mutect2, varscan2
- OR6T1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV58306859, COSV58308509; called by muse, mutect2, varscan2
- OR6X1 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV60009875, COSV60010189; called by muse, mutect2, varscan2
- OR8D4 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs772955197, COSV58431040, COSV58431670; called by muse, mutect2, varscan2
- PARP4 | c.3158C>T p.S1053F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV67963238; called by muse, mutect2, varscan2
- PAX6 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV53794822; called by muse, mutect2, varscan2
- PCDHA12 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as rs782151232, COSV56494874; called by mutect2, varscan2
- PCDHB3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV50564022; called by muse, mutect2, varscan2
- PCDHGC5 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV52760355; called by muse, mutect2, varscan2
- PCNT | c.3868C>T p.R1290C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs990450574, COSV64031058; called by mutect2, varscan2
- PDE4B | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1226914667, COSV58475112; called by muse, mutect2, varscan2
- PEG3 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs143073381; called by mutect2, varscan2
- PGRMC1 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV54293250; called by mutect2, varscan2
- PHKB | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV54528952; called by mutect2, varscan2
- PIGO | c.2007G>T p.W669C | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.804); catalogued as COSV53054571; called by muse, mutect2, varscan2
- PIP4K2A | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1166116928, COSV60541255; called by muse, mutect2, varscan2
- PLA2G2D | c.239G>A p.S80N | Missense Mutation (SNP) | VAF 60/83 reads (72%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs967363344, COSV64281843; called by muse, mutect2, varscan2
- PLCH1 | c.2374G>A p.E792K (on ENST00000340059 / NM_001130960.2; = p.E804K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780182537, COSV100397543; called by muse, mutect2, varscan2
- PLEKHA5 | c.2833C>T p.P945S | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.45); PolyPhen benign (0.052); catalogued as COSV54707683; called by muse, mutect2, varscan2
- PMPCB | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 109/151 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1257530513, COSV50787106; called by muse, mutect2, varscan2
- POLQ | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV51748353; called by muse, mutect2, varscan2
- POLR2H | c.399T>A p.H133Q | Missense Mutation (SNP) | VAF 74/130 reads (57%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV52616653; called by muse, mutect2, varscan2
- PPIE | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100180131; called by muse, mutect2, varscan2
- PRKG2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867660938, COSV52320273; called by muse, mutect2, varscan2
- PROKR2 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54088153; called by muse, mutect2, varscan2
- PROS1 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV101260283, COSV67776463; called by muse, mutect2, varscan2
- PRSS21 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV50051847; called by muse, mutect2, varscan2
- PTCRA | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs766274816, COSV58976443; called by muse, mutect2, varscan2
- PTRH1 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV58853899; called by muse, mutect2, varscan2
- RAD9A | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57236847; called by muse, mutect2, varscan2
- RBBP4 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV65133043; called by muse, mutect2, varscan2
- RHCG | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV51517407; called by muse, mutect2, varscan2
- RNF24 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.086); catalogued as COSV60192375; called by muse, mutect2, varscan2
- RPS6KC1 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100873987; called by muse, mutect2, varscan2
- RUVBL2 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 36/63 reads (57%) | catalogued as COSV99669122; called by muse, mutect2, varscan2
- SAMSN1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53474773; called by muse, mutect2, varscan2
- SCGB1D1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV60377856; called by muse, mutect2, varscan2
- SCN10A | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0.019); catalogued as COSV71862305; called by mutect2, varscan2
- SCN5A | c.5995G>A p.E1999K (on ENST00000333535 / NM_198056.3; = p.E1998K on NM_000335.5) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV61133764; called by mutect2, varscan2
- SCUBE3 | c.2400G>A p.K800= | Splice Region (SNP) | VAF 27/178 reads (15%) | catalogued as COSV51458956; called by muse, varscan2
- SDE2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 85/141 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55252204; called by muse, mutect2, varscan2
- SERPINA10 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56229116; called by muse, mutect2, varscan2
- SERPINH1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100825122; called by muse, mutect2, varscan2
- SIAH3 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs764434486, COSV68552564; called by muse, mutect2
- SIGLEC6 | c.1014G>A p.W338* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as rs779362570, COSV58436051; called by muse, mutect2, varscan2
- SIGLEC7 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs759671422, COSV58315054; called by muse, mutect2, varscan2
- SLC26A3 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.43); PolyPhen benign (0.094); catalogued as rs201969535, COSV60641258; called by muse, mutect2, varscan2
- SLC27A4 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as COSV55961076; called by muse, mutect2, varscan2
- SLC32A1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54147746; called by muse, mutect2, varscan2
- SLC4A8 | c.2481G>A p.M827I | Missense Mutation (SNP) | VAF 53/61 reads (87%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV60656251; called by muse, mutect2, varscan2
- SLC6A2 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567453621, COSV54920440; called by muse, mutect2, varscan2
- SLITRK4 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62024000, COSV62025364; called by muse, mutect2, varscan2
- SMC1B | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV62532137; called by muse, varscan2
- SORCS3 | c.2868G>A p.K956= | Splice Region (SNP) | VAF 33/63 reads (52%) | catalogued as rs576611721, COSV63794949; called by muse, mutect2, varscan2
- SPINT2 | c.379T>C p.F127L | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV56647344; called by muse, mutect2, varscan2
- SPOCK1 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs267600350, COSV56458405; called by mutect2, varscan2
- STYX | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); catalogued as COSV63463598; called by muse, mutect2, varscan2
- SYNE1 | c.604G>A p.D202N (on ENST00000367255 / NM_182961.4; = p.D209N on NM_033071.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV55047699, COSV55050267, COSV55079045; called by muse, mutect2
- TAF1L | c.4751G>T p.R1584L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV54265808; called by muse, mutect2, varscan2
- TAGAP | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as COSV57852709; called by muse, mutect2, varscan2
- TAS2R16 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as COSV50798133; called by muse, mutect2, varscan2
- TBC1D10A | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 79/145 reads (54%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV53165178; called by muse, mutect2, varscan2
- TDRD1 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267602371, COSV52592542; called by muse, mutect2, varscan2
- TECTA | c.3544-1G>A p.X1182_splice | Splice Site (SNP) | VAF 82/323 reads (25%) | catalogued as COSV50758433; called by muse, mutect2, varscan2
- TENM4 | c.4753G>A p.E1585K | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV53652208; called by muse, mutect2, varscan2
- TFE3 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59948393; called by muse, varscan2
- TGM7 | c.971A>C p.E324A | Missense Mutation (SNP) | VAF 106/137 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV71772991; called by muse, mutect2, varscan2
- THAP12 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs1241898216, COSV52611811; called by muse, mutect2, varscan2
- THBS2 | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 25/43 reads (58%) | catalogued as COSV64681014; called by muse, mutect2, varscan2
- TICAM1 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV50235984; called by muse, mutect2
- TLR6 | c.1793T>G p.L598W | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV67935538; called by muse, mutect2, varscan2
- TMC5 | c.2275G>A p.G759R (on ENST00000396229 / NM_001105248.1; = p.G513R on NM_024780.5) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54907368; called by muse, mutect2, varscan2
- TNS3 | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as COSV60795503; called by muse, mutect2, varscan2
- TOB2 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV59501448; called by muse, mutect2, varscan2
- TRIM9 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV53621767; called by muse, mutect2, varscan2
- TRPM2 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs267606156, COSV100309514, COSV55968287; called by muse, mutect2, varscan2
- TRPV6 | c.2027G>A p.R676K | Missense Mutation (SNP) | VAF 100/151 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV63892840; called by muse, mutect2, varscan2
- TTC39C | c.1675G>A p.G559S (on ENST00000317571 / NM_001135993.2; = p.G498S on NM_153211.4) | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV58219544; called by muse, varscan2
- TTN | c.75558G>A p.W25186* (on ENST00000591111; = p.W17762* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 33/40 reads (83%) | catalogued as COSV60219967; called by muse, mutect2, varscan2
- UBQLN3 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV61164941; called by muse, mutect2, varscan2
- UNC45B | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52098705; called by muse, varscan2
- WDR62 | c.2962C>T p.P988S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.412); catalogued as COSV54337627; called by muse, mutect2, varscan2
- ZBED1 | c.1793T>C p.F598S | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58136801; called by muse, mutect2, varscan2
- ZCCHC3 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs768862898, COSV66643513; called by muse, mutect2, varscan2
- ZCCHC7 | c.1235A>G p.K412R | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.287); catalogued as COSV60959696; called by muse, mutect2, varscan2
- ZEB2 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57961987; called by muse, mutect2, varscan2
- ZNF208 | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68110296; called by muse, varscan2
- ZNF425 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV65202078; called by muse, mutect2
- ZNF527 | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV62233057; called by mutect2, varscan2
- ZNF808 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs1326329116, COSV63120936; called by muse, mutect2, varscan2
- ZP2 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267604453, COSV54812388; called by mutect2, varscan2
- ZP4 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 56/71 reads (79%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV63912892; called by muse, mutect2, varscan2
- ZSCAN20 | c.2380T>A p.Y794N | Missense Mutation (SNP) | VAF 75/97 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63683816; called by muse, mutect2, varscan2
- CCNA1 | c.911_912del p.Y304Sfs*3 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by pindel, varscan2
- FLG | c.4579A>T p.R1527W | Missense Mutation (SNP) | VAF 285/345 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by mutect2, varscan2
- ABCC10 | c.177C>T p.I59= (on ENST00000372530 / NM_001198934.2; = p.I16= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV55091734; called by muse, mutect2, varscan2
- ADAMTS12 | c.525C>T p.F175= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV61259640; called by muse, mutect2, varscan2
- ADAMTS19 | c.2230C>T p.L744= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as COSV50767749, COSV99078966; called by muse, mutect2, varscan2
- ADGRG4 | c.2982C>T p.I994= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV54962554; called by muse, mutect2, varscan2
- AGTR2 | c.178C>T p.L60= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV64156787; called by muse, mutect2, varscan2
- ALDH3A1 | c.33C>T p.A11= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs1232489890, COSV99855982; called by muse, mutect2
- ALS2CL | c.1860G>A p.E620= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as COSV59672740; called by muse, mutect2, varscan2
- ANGPTL7 | c.600G>A p.G200= | Silent (SNP) | VAF 34/41 reads (83%) | catalogued as COSV63873753; called by muse, varscan2
- AP1B1 | c.822G>A p.L274= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV58021036; called by muse, mutect2, varscan2
- ARSJ | c.1545C>T p.I515= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV59538696; called by muse, varscan2
- ASB15 | c.288G>A p.L96= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV51928047; called by muse, mutect2
- ATP1A3 | c.1941C>T p.I647= (on ENST00000545399 / NM_001256214.2; = p.I634= on NM_152296.5) | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs1276971667, COSV57489755; called by mutect2, varscan2
- CACNA1C | c.2301G>A p.K767= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV59750109; called by muse, mutect2, varscan2
- CATSPERB | c.405C>T p.I135= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV56431325; called by muse, mutect2, varscan2
- CPA6 | c.186A>G p.Q62= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV52737294; called by muse, mutect2, varscan2
- CSMD1 | c.5421C>T p.F1807= (on ENST00000520002; = p.F1806= on NM_033225.6) | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV59309178; called by muse, mutect2, varscan2
- CTDP1 | c.1794C>T p.V598= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as COSV50000037; called by muse, mutect2, varscan2
- CYP4A11 | c.627G>A p.Q209= | Silent (SNP) | VAF 42/53 reads (79%) | catalogued as COSV60224724; called by muse, mutect2, varscan2
- DGCR8 | c.2253G>A p.K751= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV52814468; called by muse, varscan2
- DNAH7 | c.5715C>T p.V1905= | Silent (SNP) | VAF 44/60 reads (73%) | catalogued as rs772642319, COSV56776384; called by muse, mutect2, varscan2
- DSCAM | c.5409C>T p.S1803= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV68032213; called by muse, mutect2, varscan2
- DSCAM | c.63C>T p.H21= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV68648841; called by muse, mutect2, varscan2
- DSG1 | c.2065C>T p.L689= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as COSV57137802; called by muse, mutect2, varscan2
- DYNC2H1 | c.4071C>T p.G1357= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1400739832, COSV62101081; called by muse, mutect2, varscan2
- EPHA2 | c.945G>A p.R315= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as COSV100626215; called by muse, mutect2, varscan2
- EPHB3 | c.1494C>T p.A498= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV57807831; called by muse, mutect2, varscan2
- ERBB4 | c.3522G>A p.R1174= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV100726527; called by muse, mutect2, varscan2
- EVC | c.879C>T p.Y293= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV53836021; called by mutect2, varscan2
- FAM83B | c.195G>A p.L65= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV60924789; called by muse, mutect2, varscan2
- FRYL | c.7338C>T p.F2446= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs868200183, COSV51955162; called by mutect2, varscan2
- GNAI1 | c.271T>C p.L91= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV63524295; called by muse, mutect2, varscan2
- GPR158 | c.2241G>A p.K747= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as rs771439665, COSV66277327; called by muse, mutect2, varscan2
- GRIA1 | c.1161G>A p.K387= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs781595034, COSV53615161; called by muse, mutect2, varscan2
- GRIN2A | c.3018G>A p.A1006= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs761132463, COSV58037726; called by mutect2, varscan2
- GRK7 | c.1368G>A p.T456= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs762291728, COSV53821530; called by mutect2, varscan2
- HIF3A | c.480G>A p.T160= (on ENST00000377670 / NM_152795.4; = p.T91= on NM_022462.4) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs368394094; called by muse, mutect2, varscan2
- HOXB8 | c.111C>T p.T37= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs1022189335, COSV53311136; called by muse, varscan2
- IGSF9B | c.3528G>A p.R1176= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV58068131; called by muse, mutect2, varscan2
- ITGAE | c.75G>A p.R25= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs755505153, COSV53997393; called by muse, mutect2, varscan2
- KLHL13 | c.561C>T p.L187= | Silent (SNP) | VAF 61/152 reads (40%) | catalogued as COSV53250898; called by muse, mutect2, varscan2
- KRT12 | c.228C>T p.S76= | Silent (SNP) | VAF 53/103 reads (51%) | catalogued as COSV52431866; called by muse, mutect2, varscan2
- LDOC1 | c.366C>T p.L122= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs782107536, COSV100983185; called by muse, mutect2, varscan2
- MEF2B | c.660G>A p.G220= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV99364902; called by muse, mutect2
- MEFV | c.1419G>A p.L473= | Silent (SNP) | VAF 62/131 reads (47%) | catalogued as COSV54825322; called by muse, mutect2, varscan2
- MRC2 | c.3789G>A p.Q1263= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV57642524; called by muse, mutect2, varscan2
- MRGPRX1 | c.681C>T p.L227= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV57108787; called by muse, mutect2, varscan2
- MUC16 | c.18825A>T p.S6275= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV67481001; called by muse, mutect2, varscan2
- NEK4 | c.117C>T p.L39= | Silent (SNP) | VAF 74/156 reads (47%) | catalogued as COSV51782057; called by muse, mutect2, varscan2
- NEXMIF | c.486G>A p.G162= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV50061359; called by muse, mutect2, varscan2
- NLRC3 | c.657C>T p.D219= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs369562107; called by mutect2, varscan2
- NPAP1 | c.390A>C p.P130= | Silent (SNP) | VAF 40/56 reads (71%) | catalogued as COSV100274961, COSV61509511; called by muse, mutect2, varscan2
- NPY4R | c.210G>A p.K70= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as rs868974104, COSV65398610; called by muse, mutect2, varscan2
- OPRM1 | c.1035C>T p.F345= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as COSV57676408, COSV57681571; called by muse, varscan2
- OR13F1 | c.186C>T p.F62= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as rs868115303, COSV58252155, COSV58252225; called by muse, mutect2, varscan2
- OR2A5 | c.366G>A p.R122= | Silent (SNP) | VAF 194/290 reads (67%) | catalogued as COSV101278758, COSV68738957; called by muse, mutect2, varscan2
- OR2B2 | c.222C>T p.T74= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100308105, COSV57580328; called by muse, mutect2, varscan2
- OR2J3 | c.606C>T p.L202= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV65849452; called by muse, mutect2, varscan2
- OR4C12 | c.330C>T p.I110= | Silent (SNP) | VAF 50/88 reads (57%) | catalogued as COSV58859529; called by muse, mutect2, varscan2
- OR52M1 | c.540C>T p.S180= | Silent (SNP) | VAF 40/73 reads (55%) | catalogued as COSV64172405; called by muse, mutect2, varscan2
- OR5AK2 | c.822C>T p.A274= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100476091; called by muse, mutect2, varscan2
- PATZ1 | c.1254T>C p.C418= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV53230502; called by muse, mutect2, varscan2
- PCDH19 | c.3438C>T p.I1146= (on ENST00000373034 / NM_001184880.2; = p.I1098= on NM_020766.3) | Silent (SNP) | VAF 46/140 reads (33%) | catalogued as COSV55268063; called by muse, mutect2, varscan2
- PCDHB6 | c.2118C>T p.F706= | Silent (SNP) | VAF 111/216 reads (51%) | catalogued as rs1406746078, COSV50689820; called by muse, mutect2, varscan2
- PDS5A | c.1923G>A p.G641= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV57828776; called by muse, mutect2, varscan2
- PKDREJ | c.1218G>A p.L406= | Silent (SNP) | VAF 79/159 reads (50%) | catalogued as COSV53551377; called by muse, mutect2, varscan2
- PKHD1L1 | c.549G>A p.G183= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1329747913, COSV65748593; called by muse, mutect2, varscan2
- PLAA | c.763C>T p.L255= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as COSV68305347; called by muse, mutect2, varscan2
- PLS3 | c.1467G>A p.G489= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV56780821; called by muse, mutect2, varscan2
- PMFBP1 | c.198G>A p.E66= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs199806183, COSV52828979; called by muse, mutect2, varscan2
- PPP2R2B | c.1188G>A p.G396= (on ENST00000394409; = p.G462= on NM_181674.2) | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as COSV60766236, COSV60772492; called by muse, mutect2, varscan2
- PRKAA2 | c.1353G>A p.V451= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV64805164; called by muse, mutect2, varscan2
- PROKR2 | c.1071G>A p.R357= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV54088140; called by muse, mutect2, varscan2
- RAD9A | c.819G>A p.Q273= | Silent (SNP) | VAF 62/132 reads (47%) | catalogued as COSV100334999; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1164G>A p.Q388= | Silent (SNP) | VAF 51/103 reads (50%) | catalogued as COSV54583752; called by muse, mutect2, varscan2
- RASSF6 | c.675C>T p.F225= (on ENST00000342081 / NM_201431.2; = p.F193= on NM_177532.5) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV56720032; called by mutect2, varscan2
- RLIM | c.444G>A p.G148= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as COSV60328026; called by muse, mutect2, varscan2
- RNF10 | c.384C>T p.S128= | Silent (SNP) | VAF 39/51 reads (76%) | catalogued as COSV58047025; called by muse, mutect2, varscan2
- RNF152 | c.354C>T p.G118= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV57187007; called by muse, mutect2, varscan2
- RPS6KC1 | c.888C>T p.Y296= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100873986; called by muse, mutect2, varscan2
- RUVBL2 | c.435C>T p.I145= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as COSV99669121; called by muse, mutect2, varscan2
- SCMH1 | c.891C>T p.S297= (on ENST00000326197 / NM_001031694.2; = p.S250= on NM_012236.4) | Silent (SNP) | VAF 100/130 reads (77%) | catalogued as COSV58236062; called by muse, mutect2, varscan2
- SCN11A | c.2038T>C p.L680= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV56574531; called by muse, mutect2, varscan2
- SLC22A14 | c.384C>T p.F128= | Silent (SNP) | VAF 80/158 reads (51%) | catalogued as rs866099917, COSV56198635; called by muse, varscan2
- SLC22A23 | c.1383C>T p.L461= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV66678716; called by muse, mutect2
- SLC28A2 | c.525C>T p.I175= | Silent (SNP) | VAF 26/34 reads (76%) | catalogued as COSV61664772; called by muse, mutect2, varscan2
- SLC4A8 | c.2880G>A p.L960= | Silent (SNP) | VAF 39/60 reads (65%) | catalogued as COSV60656267; called by muse, mutect2, varscan2
- SLC6A20 | c.1266G>A p.K422= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV62072085; called by muse, mutect2, varscan2
- SLC6A20 | c.432C>T p.S144= | Silent (SNP) | VAF 43/173 reads (25%) | catalogued as COSV62072096; called by muse, mutect2, varscan2
- SLC9A6 | c.1450C>T p.L484= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV65787827; called by muse, mutect2, varscan2
- SLITRK4 | c.1822C>A p.R608= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as COSV62022465, COSV62025359; called by muse, mutect2, varscan2
- SORBS1 | c.3063C>T p.L1021= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as rs761393604, COSV53362016; called by mutect2, varscan2
- SPTLC2 | c.1347C>T p.F449= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV53641886; called by mutect2, varscan2
- SYBU | c.132C>T p.A44= (on ENST00000276646 / NM_001099754.2; = p.A43= on NM_017786.6) | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV52621302; called by muse, mutect2, varscan2
- SYTL5 | c.1602G>A p.E534= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as COSV99937448; called by muse, mutect2, varscan2
- TACC2 | c.1503G>A p.L501= | Silent (SNP) | VAF 70/94 reads (74%) | catalogued as COSV57756176, COSV57772471; called by muse, mutect2, varscan2
- TDP2 | c.675C>T p.S225= | Silent (SNP) | VAF 75/455 reads (16%) | catalogued as COSV61968127; called by muse, mutect2, varscan2
- TET1 | c.2445T>C p.H815= | Silent (SNP) | VAF 55/81 reads (68%) | catalogued as rs371505599; called by muse, mutect2, varscan2
- TEX15 | c.1912T>C p.L638= (on ENST00000256246; = p.L1021= on NM_001350162.2) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV56350345; called by muse, mutect2, varscan2
- TLR4 | c.543C>T p.D181= (on ENST00000355622 / NM_138554.5; = p.D141= on NM_003266.4) | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs763536574, COSV62923861; called by muse, mutect2, varscan2
- TMC5 | c.645C>T p.N215= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV66867662; called by muse, mutect2, varscan2
- TMEM106A | c.168C>T p.F56= | Silent (SNP) | VAF 117/217 reads (54%) | catalogued as rs768048129, COSV57832842; called by muse, varscan2
- TRIM31 | c.438C>T p.I146= | Silent (SNP) | VAF 191/275 reads (69%) | catalogued as rs1562049234, COSV65060033; called by muse, varscan2
- TXNDC5 | c.304C>T p.L102= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs777452477, COSV101124348; called by muse, mutect2, varscan2
- TXNDC5 | c.303C>T p.D101= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV101124349; called by muse, mutect2, varscan2
- UNC5A | c.1347C>T p.F449= | Silent (SNP) | VAF 54/107 reads (50%) | catalogued as COSV99994837; called by muse, mutect2, varscan2
- UPP1 | c.513C>T p.V171= | Silent (SNP) | VAF 30/163 reads (18%) | catalogued as COSV57978198; called by muse, mutect2, varscan2
- ZBTB7B | c.612C>T p.P204= (on ENST00000292176; = p.P238= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV52694028; called by muse, mutect2, varscan2
- ZFP42 | c.678C>T p.F226= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs754892437, COSV58817528; called by mutect2, varscan2
- ZNF275 | c.822C>T p.F274= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV64704012; called by muse, mutect2, varscan2
- ZNF335 | c.1794C>T p.S598= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1329856224, COSV59819198; called by muse, mutect2, varscan2
- ZNF521 | c.771C>T p.F257= | Silent (SNP) | VAF 33/43 reads (77%) | catalogued as COSV64122089, COSV64129818; called by muse, mutect2, varscan2
- ZNF534 | c.498C>T p.F166= (on ENST00000332323 / NM_001143939.3; = p.F153= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV56519577; called by muse, mutect2
- ZNF556 | c.627G>A p.G209= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs1460102620, COSV56913305; called by muse, mutect2, varscan2
- ZNF75D | c.1236C>T p.F412= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as COSV66133172; called by muse, mutect2, varscan2
- ZNF777 | c.1815C>T p.P605= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs1487458636, COSV99925262; called by muse, mutect2, varscan2
- MIR520A | n.23G>A | RNA (SNP) | VAF 31/135 reads (23%) | called by muse, mutect2, varscan2
- PLCB1 | c.3423+11876C>T | Intron (SNP) | VAF 33/43 reads (77%) | catalogued as COSV100571678; called by mutect2, varscan2
- SNORD115-30 | n.55C>T | RNA (SNP) | VAF 143/208 reads (69%) | called by muse, mutect2, varscan2
- TPM1 | c.563+266C>T | Intron (SNP) | VAF 50/60 reads (83%) | catalogued as rs201813515, COSV51265513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.34265-2978C>T | Intron (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100621112; called by muse, mutect2, varscan2
